Somatic mutation profile of tumor specimen TCGA-50-5049-01A (aliquot TCGA-50-5049-01A-01D-1625-08) from TCGA case TCGA-50-5049, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.0 years (25,577 days).
Specimen TCGA-50-5049-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddb4676c-ef89-4187-9aee-8960d4782bd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5049-10A (Blood Derived Normal), aliquot TCGA-50-5049-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c95d846-6ef5-4810-a389-7444d4873fef

The open-access MAF lists 819 somatic variants for this specimen: 630 protein-altering or splice-affecting, 166 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 536, Silent 166, Nonsense Mutation 47, Frame Shift Del 17, Splice Site 16, Intron 10, Frame Shift Ins 8, RNA 6, Splice Region 5, 3'UTR 3, 5'Flank 2, 5'UTR 1.

Variants (750 of 819; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3190G>T p.V1064L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775447163, COSV99288213; called by mutect2, varscan2
- ABCA13 | c.296G>T p.R99M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101329980; called by muse, mutect2
- ABCB5 | c.2017C>A p.L673I (on ENST00000404938 / NM_001163941.2; = p.L228I on NM_178559.6) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.162); catalogued as COSV51712007; called by muse, mutect2, varscan2
- ABCB5 | c.3511C>A p.L1171I (on ENST00000404938 / NM_001163941.2; = p.L726I on NM_178559.6) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.052); catalogued as COSV51712019, COSV51723672; called by muse, mutect2, varscan2
- ABCB8 | c.617G>T p.G206V (on ENST00000297504 / NM_001282291.2; = p.G189V on NM_007188.5) | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52505761; called by muse, mutect2, varscan2
- ABCC9 | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV99685096; called by muse, mutect2, varscan2
- ABCG8 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs758668360, COSV55393995; called by muse, mutect2, varscan2
- ABL2 | c.2895G>T p.Q965H (on ENST00000502732 / NM_007314.4; = p.Q950H on NM_005158.5) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV61015956; called by muse, mutect2, varscan2
- AC127029.3 | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV60111160; called by muse, mutect2
- ACVR1B | c.1232G>T p.W411L | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99231346; called by muse, mutect2, varscan2
- ADAM19 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV57431869; called by muse, mutect2, varscan2
- ADAM9 | c.1529C>A p.A510D | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as COSV65960605; called by muse, mutect2
- ADAMTS16 | c.3585C>A p.H1195Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV56993257; called by muse, mutect2
- ADAMTS18 | c.1112G>T p.W371L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51417483; called by muse, mutect2, varscan2
- ADAMTS5 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.672); catalogued as COSV53180124; called by muse, mutect2, varscan2
- ADARB2 | c.1394T>A p.F465Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101186781; called by muse, mutect2, varscan2
- ADCY4 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99353081; called by mutect2, varscan2
- ADGRG4 | c.671G>T p.R224M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99794930; called by muse, mutect2, varscan2
- ADGRG4 | c.5626C>T p.Q1876* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV54958576; called by muse, mutect2, varscan2
- ADGRG7 | c.946+1G>T p.X316_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV56297729; called by muse, mutect2
- ADHFE1 | c.689A>T p.H230L | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV52556054; called by muse, mutect2, varscan2
- ADNP2 | c.2933G>T p.R978I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51539677; called by muse, mutect2, varscan2
- ADORA1 | c.342G>T p.R114= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as COSV55142805; called by muse, mutect2, varscan2
- AHNAK2 | c.8552C>G p.S2851C | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as COSV60918357, COSV60932351; called by muse, mutect2, varscan2
- ALDH1A2 | c.656C>A p.A219E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99990558; called by muse, mutect2, varscan2
- AMPH | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV57745047; called by muse, mutect2, varscan2
- ANK2 | c.6558G>T p.E2186D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.359); catalogued as COSV52167286; called by muse, mutect2, varscan2
- ANKRD30A | c.237G>T p.W79C (on ENST00000611781; = p.W23C on NM_052997.2) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1041973101, COSV100653168; called by muse, mutect2, varscan2
- ANKRD35 | c.1721C>A p.A574D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV62910660; called by muse, mutect2, varscan2
- ANLN | c.2545G>C p.A849P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56077075; called by muse, mutect2, varscan2
- APBA2 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV68792200; called by muse, mutect2, varscan2
- APBB2 | c.1339A>G p.I447V (on ENST00000295974 / NM_001166050.2; = p.I448V on NM_004307.2) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55954465; called by muse, mutect2
- APC | c.423-1G>T p.X141_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as CS011019, CS043350, CS992994, COSV57323544, COSV57337711, COSV57351315; called by muse, mutect2, varscan2
- APLP1 | c.1671G>T p.R557S (on ENST00000221891 / NM_001024807.3; = p.R556S on NM_005166.4) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.547); catalogued as COSV55704015; called by muse, mutect2, varscan2
- ARHGAP25 | c.1424C>A p.S475* (on ENST00000409202 / NM_001007231.3; = p.S467* on NM_014882.3) | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as COSV54903659, COSV54905677; called by muse, mutect2, varscan2
- ARHGAP36 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52268036; called by muse, mutect2, varscan2
- ARHGEF17 | c.4309G>T p.E1437* | Nonsense Mutation (SNP) | VAF 9/148 reads (6%) | catalogued as COSV55233641; called by muse, mutect2
- ARID5A | c.1534A>T p.T512S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV62591273; called by muse, mutect2
- ARIH1 | c.1335G>T p.M445I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV65911901; called by muse, mutect2, varscan2
- ARMC1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV52533933, COSV52534435; called by muse, mutect2, varscan2
- ASB16 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.227); catalogued as COSV53235181; called by muse, mutect2, varscan2
- ASB18 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV68960617; called by muse, mutect2
- ASGR2 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54690535; called by muse, mutect2, varscan2
- ASPM | c.4898G>C p.R1633P | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54130632, COSV54131811; called by muse, mutect2, varscan2
- ATP6V1A | c.1072C>A p.L358I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56362807; called by muse, mutect2, varscan2
- ATP6V1C1 | c.521A>T p.D174V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67778228; called by muse, mutect2
- ATP8A2 | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54957528; called by muse, mutect2, varscan2
- B3GALNT1 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV100251957, COSV57579825; called by muse, mutect2
- BARD1 | c.760A>T p.I254L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99638286; called by muse, mutect2, varscan2
- BARHL1 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV55037907; called by muse, mutect2, varscan2
- BASP1 | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV59471518; called by muse, mutect2, varscan2
- BCORL1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV54398364; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV99958640; called by muse, mutect2
- BMP10 | c.245C>A p.P82Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54895618; called by muse, mutect2, varscan2
- BNC1 | c.2129C>G p.A710G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV61757822; called by muse, mutect2
- BPIFA1 | c.489C>G p.I163M | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV62824669; called by muse, mutect2, varscan2
- BRINP3 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66527655; called by muse, mutect2, varscan2
- BRSK1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1231206905, COSV58667459; called by muse, mutect2, varscan2
- BTN1A1 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99764274; called by muse, mutect2
- C1QTNF4 | c.730T>A p.S244T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100209230; called by mutect2, varscan2
- C8orf37 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54412679; called by muse, mutect2
- CA3 | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53410187; called by muse, mutect2, varscan2
- CACNA1C | c.5956T>A p.S1986T (on ENST00000399634 / NM_001167625.1; = p.S1915T on NM_000719.7) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.031); catalogued as COSV100217195; called by muse, mutect2, varscan2
- CACNA2D1 | c.3176G>T p.C1059F (on ENST00000356253 / NM_001366867.1; = p.C1047F on NM_000722.4) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62381905; called by muse, mutect2
- CACNA2D1 | c.3047T>C p.I1016T (on ENST00000356253 / NM_001366867.1; = p.I1004T on NM_000722.4) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV62381913; called by muse, mutect2, varscan2
- CACNA2D4 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.736); catalogued as COSV54952007; called by muse, mutect2
- CADM1 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); catalogued as COSV59013354; called by muse, mutect2, varscan2
- CALD1 | c.1765G>C p.E589Q (on ENST00000361675 / NM_033138.4; = p.E334Q on NM_004342.7) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV62648873; called by muse, mutect2, varscan2
- CBY2 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs1408906132, COSV60118641; called by muse, mutect2, varscan2
- CCDC141 | c.1810G>T p.D604Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV99836475; called by muse, mutect2, varscan2
- CCDC8 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100281955; called by muse, mutect2
- CCDC88A | c.2997+1G>T p.X999_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV55063621; called by muse, mutect2, varscan2
- CCNA1 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV55222163; called by muse, mutect2, varscan2
- CCNB3 | c.4051T>C p.Y1351H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99328739; called by muse, mutect2
- CCT8L2 | c.529A>T p.M177L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100742621; called by muse, mutect2, varscan2
- CD1B | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.695); catalogued as COSV100939189; called by muse, mutect2, varscan2
- CD1B | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV63804452; called by muse, mutect2, varscan2
- CD33 | c.785T>C p.I262T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs1167516569, COSV51802373; called by muse, mutect2, varscan2
- CDC27 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99294420; called by muse, mutect2, varscan2
- CDH10 | c.2150G>T p.R717M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52584402; called by muse, mutect2, varscan2
- CDH11 | c.2142C>G p.S714R | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV51765441; called by muse, mutect2
- CDH12 | c.2014G>C p.A672P | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66413472; called by muse, mutect2
- CDH17 | c.271A>T p.T91S | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV50330489; called by muse, mutect2
- CDH24 | c.2095G>T p.D699Y | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943643; called by muse, mutect2, varscan2
- CDK11B | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as COSV58339017; called by muse, mutect2, varscan2
- CDK18 | c.117C>G p.N39K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.287); catalogued as COSV100773973; called by muse, mutect2, varscan2
- CENPF | c.3694G>T p.E1232* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV65275734; called by muse, mutect2, varscan2
- CENPP | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | catalogued as COSV65039303; called by muse, mutect2, varscan2
- CEP135 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV57260784, COSV99954689; called by muse, mutect2, varscan2
- CEP164 | c.3921G>C p.K1307N | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.279); catalogued as COSV54042425; called by muse, mutect2, varscan2
- CERS2 | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV54985092; called by muse, mutect2, varscan2
- CFAP46 | c.7584A>T p.R2528S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.103); catalogued as COSV99584322; called by muse, mutect2, varscan2
- CFAP77 | c.248C>A p.A83E | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV100545685, COSV100546222; called by muse, mutect2, varscan2
- CHRM3 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV55092279; called by muse, mutect2, varscan2
- CHRND | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as rs145920855, COSV51321142; called by muse, mutect2, varscan2
- CLCN1 | c.301+1G>C p.X101_splice | Splice Site (SNP) | VAF 22/99 reads (22%) | catalogued as rs1222442432, COSV58370800; called by muse, mutect2, varscan2
- CLEC4M | c.944T>A p.L315Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50219752; called by muse, mutect2
- CLTC | c.638C>A p.S213* | Nonsense Mutation (SNP) | VAF 19/116 reads (16%) | catalogued as COSV52248800; called by muse, mutect2, varscan2
- CNGB3 | c.2302C>T p.H768Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV60693712; called by muse, mutect2
- COL14A1 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.435); catalogued as rs1194264170, COSV52857792; called by muse, mutect2
- COL24A1 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV65308025; called by muse, mutect2, varscan2
- COL3A1 | c.3093G>A p.K1031= | Splice Region (SNP) | VAF 7/79 reads (9%) | catalogued as COSV58590405; called by muse, mutect2
- COL3A1 | c.4211G>A p.G1404E | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58590417; called by muse, mutect2, varscan2
- COL5A2 | c.1546G>T p.G516W | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66410737; called by muse, mutect2, varscan2
- COL7A1 | c.4714G>T p.G1572W | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60396619; called by muse, mutect2
- COQ8A | c.185A>T p.D62V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV64658095; called by muse, mutect2
- CPS1 | c.129A>C p.A43= | Splice Region (SNP) | VAF 9/120 reads (8%) | catalogued as COSV51813171; called by muse, mutect2
- CPT1A | c.1701C>A p.D567E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55757159; called by muse, mutect2
- CPT1C | c.2172G>T p.M724I | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV54919928; called by muse, mutect2
- CPVL | c.1320G>C p.Q440H | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768929266, COSV55303955; called by muse, mutect2
- CRACD | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); catalogued as rs1166805601, COSV51723387; called by muse, varscan2
- CRISPLD2 | c.1154A>T p.K385I | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as rs1322392407, COSV52280267; called by muse, mutect2, varscan2
- CRMP1 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs146352571; called by mutect2, varscan2
- CTCFL | c.671T>A p.V224E | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV54775498; called by muse, mutect2, varscan2
- CYP4F12 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV61174349; called by muse, mutect2, varscan2
- DCBLD1 | c.236G>T p.R79I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV51642259; called by muse, mutect2, varscan2
- DCUN1D3 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60953836; called by muse, mutect2, varscan2
- DDO | c.757G>T p.E253* (on ENST00000368924 / NM_001368172.1; = p.E194* on NM_004032.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | catalogued as COSV64470228; called by muse, mutect2, varscan2
- DGKB | c.1705A>G p.N569D | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV51791362; called by muse, mutect2, varscan2
- DLGAP4 | c.969C>G p.C323W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59418985; called by muse, mutect2
- DMRT1 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV66521974; called by muse, mutect2
- DNAH5 | c.2308A>G p.I770V | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1318006902, COSV54232221; called by muse, mutect2
- DNAH7 | c.6812G>T p.C2271F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56769414; called by muse, mutect2, varscan2
- DNAH9 | c.4067T>A p.F1356Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV52355103; called by muse, mutect2, varscan2
- DNAJC11 | c.922A>G p.I308V | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53787542; called by muse, mutect2
- DOCK2 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99911178; called by muse, mutect2
- DOK1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.569); catalogued as COSV51208761; called by muse, mutect2
- DOLPP1 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 10/220 reads (5%) | catalogued as COSV59910555; called by muse, mutect2
- DPYD | c.1615G>C p.G539R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs142619737, CM1211631, COSV64601186, COSV99058643; called by muse, mutect2, varscan2
- DRD2 | c.808G>C p.V270L | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV60759068; called by muse, mutect2
- DSG4 | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV57392998, COSV57393782; called by muse, mutect2, varscan2
- DTNA | c.1451G>T p.R484I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52008032; called by muse, mutect2, varscan2
- DUSP2 | c.941A>G p.H314R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99997027; called by muse, mutect2, varscan2
- DZIP1 | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61266501; called by muse, mutect2, varscan2
- EFR3A | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99602665; called by muse, mutect2, varscan2
- EGF | c.2693G>C p.R898P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV54480110, COSV99491221; called by muse, mutect2, varscan2
- EGFL6 | c.1233G>T p.W411C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63634191; called by muse, mutect2, varscan2
- EHD3 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV59031327; called by muse, mutect2, varscan2
- EIF1AX | c.40A>T p.R14W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV63309324, COSV63309357; called by muse, mutect2, varscan2
- EIF2AK1 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV52240385; called by muse, mutect2, varscan2
- ELOVL2 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV61155759; called by muse, mutect2, varscan2
- ELOVL6 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100165083; called by muse, mutect2, varscan2
- EML1 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99214729; called by muse, mutect2
- EPHA7 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100992373; called by muse, mutect2
- ERBB4 | c.3376C>T p.Q1126* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as COSV61493962; called by muse, mutect2
- FAM161A | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101295683; called by muse, mutect2, varscan2
- FAM83B | c.2180G>T p.R727I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.135); catalogued as COSV60923081; called by muse, mutect2, varscan2
- FANCG | c.1631G>T p.C544F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62720957; called by muse, mutect2, varscan2
- FAP | c.1982C>T p.T661I | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV51862968; called by muse, mutect2, varscan2
- FAT4 | c.4682G>A p.G1561E | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67889316; called by muse, mutect2
- FBLN5 | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV50904620; called by muse, mutect2
- FBN1 | c.6478G>T p.A2160S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as CM054687, CX077465, COSV100354296; called by muse, mutect2, varscan2
- FBXO21 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57971825, COSV57973313; called by muse, mutect2
- FBXO30 | c.1412G>C p.S471T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV52791510; called by muse, mutect2, varscan2
- FBXO38 | c.1919-1G>C p.X640_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV57028659; called by muse, mutect2
- FCER1A | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.539); catalogued as COSV63667505; called by muse, mutect2, varscan2
- FCRL1 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV63825866; called by muse, mutect2, varscan2
- FCRL2 | c.1495C>A p.Q499K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV100829862; called by muse, mutect2, varscan2
- FFAR2 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as COSV55832568; called by muse, mutect2, varscan2
- FLG | c.8417T>C p.V2806A | Missense Mutation (SNP) | VAF 36/565 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV64243082; called by muse, mutect2
- FLG | c.6785C>A p.S2262Y | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV64243084; called by muse, mutect2, varscan2
- FLNC | c.8132G>T p.G2711V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99972457; called by muse, mutect2, varscan2
- FLT1 | c.3769C>A p.R1257S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV99151056; called by muse, mutect2
- FLT1 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV56730694; called by muse, mutect2, varscan2
- FNDC3B | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV61044033; called by muse, mutect2, varscan2
- FOXG1 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100486635, COSV57396851; called by muse, mutect2
- FRAS1 | c.11311C>T p.P3771S | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53618619; called by muse, mutect2
- FSCB | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.414); catalogued as rs1361273922, COSV61218439; called by muse, mutect2, varscan2
- FSD2 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV58010653; called by muse, mutect2
- FSHR | c.288A>T p.K96N | Missense Mutation (SNP) | VAF 89/350 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV58625767; called by muse, mutect2, varscan2
- FSIP2 | c.20452C>A p.P6818T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV58089077; called by muse, mutect2, varscan2
- FYB1 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV60940412; called by muse, mutect2, varscan2
- FZD4 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV72294476; called by muse, mutect2, varscan2
- GABRA1 | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50107667; called by muse, mutect2
- GABRB1 | c.1335T>A p.D445E | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV54985871; called by muse, mutect2, varscan2
- GABRG1 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | catalogued as COSV54955997, COSV99778949; called by muse, mutect2
- GABRG3 | c.365T>A p.M122K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61520910; called by muse, mutect2
- GAL3ST1 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV58892875; called by muse, mutect2, varscan2
- GALNT14 | c.855C>A p.F285L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541207790, COSV61102348, COSV61106411; called by muse, mutect2, varscan2
- GALNT14 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV61106417; called by muse, mutect2, varscan2
- GALR2 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs781620715, COSV100203479; called by muse, mutect2, varscan2
- GATAD2A | c.785G>C p.S262T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV99389907; called by muse, mutect2, varscan2
- GBP4 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as COSV100864336; called by muse, mutect2, varscan2
- GIMAP5 | c.859_860insA p.V287Dfs*31 | Frame Shift Ins (INS) | VAF 7/50 reads (14%) | catalogued as COSV100500224; called by mutect2, varscan2
- GJA8 | c.275A>T p.Y92F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99569228; called by muse, mutect2, varscan2
- GLRA2 | c.704A>G p.H235R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV99490594; called by muse, mutect2, varscan2
- GLYATL2 | c.314-1G>T p.X105_splice | Splice Site (SNP) | VAF 10/94 reads (11%) | catalogued as COSV54850290; called by muse, mutect2
- GMDS | c.826G>T p.G276W | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66415742; called by muse, mutect2, varscan2
- GPATCH8 | c.1954G>T p.G652W | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.315); catalogued as COSV59195464; called by muse, mutect2, varscan2
- GPD2 | c.2057A>T p.Q686L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV60093481; called by muse, mutect2, varscan2
- GPR15 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.582); catalogued as COSV52520769; called by muse, mutect2, varscan2
- GPR32 | c.896A>C p.Q299P | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV54514807; called by muse, mutect2
- GRID2 | c.1889C>A p.T630N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV56218322; called by muse, mutect2, varscan2
- GRIK4 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV70803234; called by muse, mutect2, varscan2
- GRM1 | c.2042G>T p.R681L | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51116944, COSV51170387; called by muse, mutect2, varscan2
- GSK3B | c.922C>T p.R308* (on ENST00000264235 / NM_001146156.2; = p.R321* on NM_002093.4) | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99954896; called by mutect2, varscan2
- HAVCR1 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.449); catalogued as rs1208324580, COSV59397718, COSV59400577; called by muse, mutect2
- HEPACAM2 | c.838T>A p.Y280N (on ENST00000394468 / NM_001039372.4; = p.Y268N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59061092; called by muse, mutect2, varscan2
- HERC1 | c.8891G>T p.W2964L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.979); catalogued as COSV101496442; called by muse, varscan2
- HGF | c.1982C>A p.A661D | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as COSV99736221; called by muse, mutect2
- HGF | c.1851G>T p.W617C | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55951307; called by muse, mutect2
- HIVEP3 | c.4346G>T p.R1449I | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56016988; called by muse, mutect2, varscan2
- HK3 | c.1588C>A p.P530T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52841224, COSV52842630; called by mutect2, varscan2
- HLX | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100854490; called by muse, mutect2, varscan2
- HMCN1 | c.6756G>T p.R2252S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); catalogued as COSV99626371; called by muse, mutect2
- HOOK1 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64619368; called by muse, mutect2, varscan2
- HPS3 | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99937278; called by muse, mutect2, varscan2
- HPS5 | c.2378G>T p.S793I (on ENST00000349215 / NM_181507.2; = p.S679I on NM_007216.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV61687597; called by mutect2, varscan2
- HSP90AA1 | c.1882A>G p.M628V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV53489367; called by muse, mutect2, varscan2
- HSPA13 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV53465501; called by muse, mutect2, varscan2
- HTR1B | c.815C>A p.S272* | Nonsense Mutation (SNP) | VAF 11/126 reads (9%) | catalogued as COSV100885344, COSV64051584; called by muse, mutect2
- HTR2C | c.1222G>T p.G408W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52214888; called by muse, mutect2, varscan2
- HYAL3 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56498237; called by muse, mutect2, varscan2
- IFNA6 | c.430A>G p.R144G | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV101207020; called by muse, mutect2
- IGF2R | c.2996G>T p.W999L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100807121, COSV63629284; called by muse, mutect2
- IL2RB | c.1297A>C p.S433R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV53426833; called by muse, mutect2
- INTS6 | c.2478A>G p.K826= | Splice Region (SNP) | VAF 4/27 reads (15%) | catalogued as COSV60878735, COSV60880398; called by muse, mutect2
- IQCN | c.2862G>T p.M954I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV62747920; called by muse, mutect2, varscan2
- IQSEC3 | c.2790C>A p.F930L (on ENST00000538872 / NM_001170738.2; = p.F627L on NM_015232.1) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV58286067; called by muse, mutect2, varscan2
- IRGC | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV54984716; called by muse, varscan2
- IRS1 | c.2065G>T p.V689F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV59337284; called by muse, mutect2, varscan2
- ITGAD | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101210403; called by muse, mutect2
- ITGAE | c.1552C>A p.L518M | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV99560690; called by muse, mutect2
- ITGAL | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.02); catalogued as COSV63322685; called by muse, mutect2
- ITGAM | c.1455G>T p.Q485H | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV54933686; called by muse, mutect2
- ITPRIPL2 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV101198160; called by muse, mutect2, varscan2
- JAK3 | c.1520A>G p.Q507R | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs140690573, COSV71686693, COSV99070385; called by muse, mutect2, varscan2
- JMJD1C | c.1015+1G>T p.X339_splice | Splice Site (SNP) | VAF 10/84 reads (12%) | catalogued as COSV67863048; called by muse, mutect2, varscan2
- JMJD1C | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV67863055; called by muse, mutect2, varscan2
- KALRN | c.5108G>A p.S1703N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs1358010223, COSV62569807; called by muse, mutect2, varscan2
- KCNK18 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs761885569, COSV100572009; called by muse, mutect2
- KCNMB2 | c.349T>A p.Y117N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64201158; called by muse, mutect2, varscan2
- KCNN1 | c.387G>T p.W129C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99715754; called by muse, mutect2, varscan2
- KDM1B | c.1794G>T p.Q598H (on ENST00000449850; = p.X366_splice on NM_153042.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV52811689; called by muse, mutect2, varscan2
- KDM4C | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101184746; called by muse, mutect2
- KIAA1549L | c.707_708insA p.S237Vfs*6 (on ENST00000321505; = p.S534Vfs*6 on NM_012194.3) | Frame Shift Ins (INS) | VAF 9/65 reads (14%) | catalogued as COSV99682970; called by mutect2, pindel, varscan2
- KIF18A | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs761811553, COSV54184076; called by muse, mutect2
- KIF4A | c.2752G>T p.A918S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100979446; called by muse, mutect2
- KIF5A | c.2962G>T p.A988S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.018); catalogued as COSV54055621; called by muse, mutect2, varscan2
- KIR3DL2 | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV99551892; called by muse, mutect2, varscan2
- KIRREL3 | c.897C>A p.Y299* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV73106574; called by muse, mutect2, varscan2
- KMO | c.610G>T p.G204* | Nonsense Mutation (SNP) | VAF 20/163 reads (12%) | catalogued as COSV63808959; called by muse, mutect2, varscan2
- KMT2B | c.7172G>T p.S2391I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV55820793; called by muse, mutect2
- KMT2C | c.3749C>A p.S1250Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100079211, COSV51451813; called by muse, mutect2, varscan2
- KRT38 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV99878137; called by muse, mutect2
- KRTAP4-12 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV67458094; called by muse, mutect2, varscan2
- LILRB4 | c.60C>A p.H20Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV54406180; called by muse, mutect2, varscan2
- LOXL3 | c.983G>T p.W328L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs762713525, COSV51208759; called by muse, mutect2, varscan2
- LRP1 | c.5125G>T p.V1709F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV54504405, COSV54514678; called by muse, mutect2, varscan2
- LRP1B | c.11098G>T p.G3700* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV67261760, COSV67282564; called by muse, mutect2, varscan2
- LRP1B | c.9173A>G p.Y3058C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1477555557, COSV67233642; called by muse, mutect2, varscan2
- LRP1B | c.4308G>T p.E1436D | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.359); catalogued as COSV67211898, COSV67254260; called by muse, mutect2, varscan2
- LRP4 | c.4537G>T p.D1513Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66135306, COSV66136374; called by muse, mutect2, varscan2
- LRP4 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.53); catalogued as COSV66136382; called by muse, mutect2
- LRP6 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV53788985; called by muse, mutect2, varscan2
- LRRC32 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as rs1565404579, COSV52634345; called by muse, varscan2
- LRRIQ1 | c.1396A>T p.K466* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV67832353; called by muse, mutect2, varscan2
- LVRN | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1561564544, COSV63497473; called by muse, mutect2, varscan2
- LYST | c.2651A>G p.K884R | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV67708210; called by muse, mutect2, varscan2
- MACF1 | c.8638G>C p.G2880R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV57126612; called by muse, mutect2, varscan2
- MAGEC3 | c.1046A>T p.Q349L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100025113; called by muse, mutect2, varscan2
- MAGEC3 | c.1047A>T p.Q349H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV100025118; called by muse, mutect2, varscan2
- MAST4 | c.5659C>T p.P1887S (on ENST00000403625 / NM_001164664.2; = p.P1698S on NM_015183.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); catalogued as rs1299277743, COSV55129214; called by muse, mutect2, varscan2
- MED12L | c.3002G>T p.S1001I | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV56382589; called by muse, mutect2
- MED24 | c.1563G>C p.E521D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.201); catalogued as COSV62419197; called by muse, mutect2, varscan2
- MEPE | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV63073131; called by muse, mutect2, varscan2
- MFAP1 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV51039407; called by muse, mutect2
- MFSD9 | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV51494226; called by muse, mutect2, varscan2
- MIS18BP1 | c.1228A>G p.N410D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV60371397; called by muse, mutect2
- MLIP | c.1299T>A p.S433R | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as COSV51431478; called by muse, mutect2, varscan2
- MLLT3 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs951584860, COSV63498357; called by muse, mutect2
- MMP10 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs1042574040, COSV54246596; called by muse, mutect2
- MMP16 | c.893C>A p.P298Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54170554; called by muse, varscan2
- MMP19 | c.520G>T p.G174W | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187616475, COSV100491132, COSV59451792; called by muse, mutect2, varscan2
- MMP7 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1246938072, COSV52772408; called by muse, mutect2
- MMRN1 | c.3101A>G p.D1034G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV53338509; called by muse, mutect2
- MPP4 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as COSV100206696; called by muse, mutect2, varscan2
- MROH7 | c.3144G>T p.K1048N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV59873328; called by muse, mutect2, varscan2
- MRPS21 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as COSV100481641, COSV58413799; called by muse, mutect2, varscan2
- MS4A7 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as rs1361550839, COSV55730135; called by muse, mutect2, varscan2
- MTTP | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.138); catalogued as rs370856172; called by mutect2, varscan2
- MUC17 | c.3035C>A p.T1012N | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1382219209, COSV60291764; called by muse, mutect2
- MUC17 | c.9320T>A p.L3107* | Nonsense Mutation (SNP) | VAF 42/290 reads (14%) | catalogued as COSV60291770; called by muse, mutect2, varscan2
- MYBPH | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV55138452; called by muse, varscan2
- MYH1 | c.2881C>A p.L961I | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs766684228, COSV99875358; called by muse, mutect2, varscan2
- MYH2 | c.2950C>A p.L984I | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV55440539, COSV55441194; called by muse, mutect2
- MYH7 | c.4057G>A p.A1353T | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100805860; called by muse, mutect2
- MYLK | c.2657C>G p.A886G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as COSV60612823; called by mutect2, varscan2
- MYO1B | c.3310G>T p.D1104Y (on ENST00000304164; = p.D1046Y on NM_012223.5) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV58432331; called by muse, mutect2, varscan2
- MYO1F | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57796235; called by muse, mutect2, varscan2
- MYOM1 | c.915A>T p.E305D | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV55293689; called by muse, mutect2
- MYRF | c.1036C>A p.P346T (on ENST00000278836 / NM_001127392.3; = p.P337T on NM_013279.4) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV53889980; called by muse, mutect2, varscan2
- N4BP1 | c.2096G>T p.R699I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV52211328; called by muse, mutect2
- NAV3 | c.1463A>T p.K488M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV57086537; called by muse, mutect2, varscan2
- NBAS | c.6361G>C p.E2121Q | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV55725403; called by muse, mutect2
- NBPF11 | c.2582G>T p.G861V | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1318187806; called by muse, mutect2, varscan2
- NCAM2 | c.1892G>A p.R631K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV53081224; called by muse, mutect2
- NEDD1 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57144112; called by muse, mutect2
- NETO2 | c.236C>G p.A79G | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.389); catalogued as COSV57453398; called by muse, mutect2, varscan2
- NEXMIF | c.3162T>A p.D1054E | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50039769; called by muse, mutect2
- NFAM1 | c.702C>G p.I234M | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV61195471; called by muse, mutect2, varscan2
- NHLH1 | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100131423; called by muse, mutect2, varscan2
- NID1 | c.2246C>A p.T749K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs778372709, COSV51617785, COSV51622070; called by muse, mutect2, varscan2
- NLRP12 | c.374C>G p.P125R | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.823); catalogued as COSV60749168; called by muse, mutect2, varscan2
- NLRP13 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100738113; called by muse, mutect2, varscan2
- NLRP13 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV61620161; called by muse, mutect2, varscan2
- NLRP3 | c.1970C>A p.T657N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60226013; called by muse, mutect2, varscan2
- NLRP3 | c.2921T>G p.L974R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60223483, COSV60226028; called by muse, mutect2
- NME8 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV52251443; called by muse, mutect2, varscan2
- NOMO1 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV99814316; called by mutect2, varscan2
- NOTCH3 | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as HM0685, COSV54637685; called by muse, mutect2
- NOTCH4 | c.2225G>C p.G742A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.533); catalogued as COSV66681441; called by muse, mutect2
- NOTCH4 | c.1194C>A p.S398R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV66681444; called by muse, mutect2, varscan2
- NOX3 | c.1494C>A p.D498E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50148789, COSV99342899; called by mutect2, varscan2
- NPHP1 | c.2142T>A p.F714L (on ENST00000393272 / NM_207181.4; = p.F715L on NM_000272.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57209365; called by muse, varscan2
- NRDE2 | c.2645T>A p.L882Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62962464; called by muse, mutect2, varscan2
- NRG1 | c.1441G>T p.V481L (on ENST00000405005 / NM_013964.5; = p.V486L on NM_013956.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.998); catalogued as COSV55150712, COSV55163333, COSV99827476; called by mutect2, varscan2
- NRP1 | c.1631A>G p.N544S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773082833, COSV55169350; called by muse, mutect2, varscan2
- NT5DC3 | c.394-1G>C p.X132_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | catalogued as COSV67321973; called by muse, mutect2, varscan2
- NUFIP2 | c.1057G>C p.V353L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV56603941; called by muse, mutect2, varscan2
- NUP205 | c.2875G>T p.D959Y | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV53660741; called by muse, mutect2
- NYNRIN | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV66843082; called by muse, mutect2
- OGDHL | c.1415A>G p.Y472C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766528428, COSV65103079; called by muse, mutect2, varscan2
- OLFM3 | c.629T>A p.L210H (on ENST00000338858 / NM_001288821.1; = p.L190H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV58795805, COSV58799811; called by muse, mutect2
- OR10G2 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1228020101, COSV73390397; called by muse, mutect2
- OR10Z1 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV63525201; called by muse, mutect2, varscan2
- OR1B1 | c.932T>A p.L311H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100506440; called by mutect2, varscan2
- OR1N2 | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV65460803; called by muse, mutect2
- OR2AK2 | c.424T>C p.C142R | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); catalogued as COSV63554597; called by muse, mutect2, varscan2
- OR2C3 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV63575244; called by muse, mutect2, varscan2
- OR2G3 | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV60682072; called by muse, varscan2
- OR2T10 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV100393586; called by muse, mutect2
- OR2T12 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.053); catalogued as rs774369822, COSV58775994; called by mutect2, varscan2
- OR2T3 | c.814A>T p.T272S | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.714); catalogued as COSV62082708; called by muse, mutect2
- OR2W3 | c.791C>A p.A264D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64457186; called by muse, mutect2
- OR4C16 | c.492G>T p.L164F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs774359624, COSV58942492; called by muse, mutect2, varscan2
- OR4D11 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57585976; called by muse, mutect2, varscan2
- OR4D2 | c.119T>C p.M40T | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1567782386, COSV73459788; called by muse, mutect2, varscan2
- OR4D6 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55660006; called by muse, mutect2, varscan2
- OR4N5 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61320807; called by muse, mutect2, varscan2
- OR5A2 | c.814del p.D272Tfs*11 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as COSV100119704, COSV57391250; called by mutect2, pindel, varscan2
- OR5B12 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56905350; called by muse, mutect2
- OR5D18 | c.782G>T p.C261F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100450609; called by muse, mutect2
- OR5T3 | c.782C>A p.T261K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV57381150; called by muse, mutect2, varscan2
- OR6Y1 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753757437, COSV56929773; called by muse, mutect2, varscan2
- OR7G1 | c.721T>A p.C241S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53317931; called by mutect2, varscan2
- OR8J3 | c.685C>G p.R229G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV56881805, COSV56881878; called by muse, mutect2, varscan2
- OR9G1 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56451205; called by muse, mutect2
- OR9K2 | c.496T>C p.C166R (on ENST00000305377; = p.C144R on NM_001005243.1) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59532306; called by muse, mutect2, varscan2
- OSCP1 | c.1038C>A p.N346K (on ENST00000356637 / NM_001330493.1; = p.N336K on NM_145047.5) | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV52486660; called by muse, mutect2, varscan2
- OXR1 | c.266G>A p.R89Q (on ENST00000442977 / NM_001198532.1; = p.R88Q on NM_018002.3) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs541833758, COSV56325280; called by muse, mutect2, varscan2
- PABPN1 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53729794, COSV53730347; called by muse, mutect2, varscan2
- PADI6 | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV61884994; called by muse, mutect2, varscan2
- PALB2 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as COSV99848227; called by muse, mutect2
- PALB2 | c.1018A>C p.N340H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV55166080; called by muse, mutect2, varscan2
- PARD3B | c.3454A>T p.K1152* (on ENST00000406610 / NM_001302769.2; = p.K1083* on NM_057177.7) | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV62515213; called by mutect2, varscan2
- PATZ1 | c.1954A>T p.N652Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV56744212; called by muse, mutect2, varscan2
- PCDH10 | c.1933C>G p.P645A | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.057); catalogued as COSV52096450; called by muse, mutect2, varscan2
- PCDH15 | c.3300G>T p.R1100S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV57329689; called by muse, varscan2
- PCDH17 | c.2785C>A p.P929T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.428); catalogued as rs887989206, COSV100931517; called by muse, mutect2
- PCDH18 | c.1687G>C p.V563L | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV61269299; called by muse, mutect2, varscan2
- PCDHA6 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV65344803; called by muse, mutect2, varscan2
- PCDHA9 | c.1554C>A p.Y518* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as rs1354549642, COSV65325748, COSV65327661; called by muse, mutect2, varscan2
- PCDHB11 | c.1461C>G p.N487K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as COSV61312186; called by muse, mutect2, varscan2
- PCDHB11 | c.2323C>A p.Q775K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV61312198; called by muse, mutect2, varscan2
- PCDHB3 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.381); catalogued as COSV50581397; called by muse, mutect2
- PCDHB4 | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99521988; called by muse, mutect2, varscan2
- PCDHGA4 | c.1585G>C p.G529R | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs1363636662, COSV99534019; called by muse, mutect2, varscan2
- PCDHGA4 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV99534025; called by muse, mutect2, varscan2
- PCDHGA5 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV53966599; called by muse, mutect2, varscan2
- PCF11 | c.3668G>T p.S1223I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53532814; called by muse, mutect2
- PCK1 | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.213); catalogued as COSV60127379; called by muse, mutect2, varscan2
- PDE10A | c.1676C>A p.A559E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100605227, COSV63098583; called by muse, mutect2, varscan2
- PDE1C | c.493-1G>T p.X165_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58517067; called by mutect2, varscan2
- PDE1C | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.687); catalogued as COSV68811900; called by muse, mutect2, varscan2
- PDE4B | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58481408; called by muse, mutect2
- PEG3 | c.3970C>A p.P1324T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV55627195; called by muse, mutect2, varscan2
- PEG3 | c.2238C>A p.D746E | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV55632626, COSV55636783; called by muse, mutect2, varscan2
- PER2 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54524592; called by muse, varscan2
- PGBD5 | c.482A>G p.Y161C (on ENST00000525115; = p.Y230C on NM_001258311.2) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1230395379, COSV58412153; called by muse, mutect2, varscan2
- PHF20L1 | c.1496G>T p.R499M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as COSV55194015; called by muse, mutect2, varscan2
- PHF21B | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV57559105; called by muse, mutect2, varscan2
- PIAS3 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.75); catalogued as COSV65171528; called by muse, mutect2, varscan2
- PIK3CG | c.284A>T p.H95L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV63249421; called by muse, mutect2, varscan2
- PIP5K1A | c.911T>A p.L304H (on ENST00000368888 / NM_001135638.2; = p.L291H on NM_003557.3) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62958561; called by muse, mutect2, varscan2
- PKHD1L1 | c.7999G>T p.A2667S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV65745300; called by muse, mutect2, varscan2
- PLCB3 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV54189413; called by muse, mutect2, varscan2
- PLCZ1 | c.610T>A p.W204R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56854025; called by muse, mutect2
- PLD5 | c.1495G>T p.A499S (on ENST00000442594; = p.A437S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.433); catalogued as COSV59150425; called by muse, mutect2, varscan2
- PLEKHG4B | c.2162A>G p.K721R (on ENST00000283426; = p.K1077R on NM_052909.5) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV52049061; called by muse, mutect2
- PLP1 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV58276999; called by muse, mutect2, varscan2
- PLPPR5 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54174331; called by muse, mutect2, varscan2
- PLXDC2 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV65917807; called by muse, mutect2
- PML | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs756426423, COSV51446174; called by muse, mutect2, varscan2
- POLR2M | c.248A>T p.K83M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs1242246296, COSV100221138; called by muse, mutect2, varscan2
- PPP1R13L | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as COSV62908759; called by muse, mutect2, varscan2
- PPP1R16B | c.518T>A p.L173H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55378981; called by muse, mutect2
- PRAMEF4 | c.447G>T p.L149F | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV52439115; called by muse, mutect2, varscan2
- PRDM9 | c.94T>A p.S32T | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV57007823; called by muse, mutect2, varscan2
- PRELP | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV58116201; called by muse, mutect2, varscan2
- PROKR2 | c.521T>A p.I174N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54087216; called by muse, mutect2
- PROS1 | c.1058C>A p.A353E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67775671; called by muse, mutect2, varscan2
- PRRG1 | c.432G>T p.L144F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV101068895; called by muse, mutect2, varscan2
- PSG11 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763851726, COSV60455919; called by muse, mutect2, varscan2
- PSG11 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1201948511, COSV60455926; called by muse, mutect2, varscan2
- PSG2 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 38/217 reads (18%) | catalogued as rs764553786, COSV61545550; called by muse, mutect2, varscan2
- PSME2 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.7); catalogued as COSV52824534; called by muse, mutect2, varscan2
- PTPN11 | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as COSV61009888; called by muse, mutect2
- PTPRC | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.291); catalogued as COSV61413701; called by muse, mutect2
- PTPRZ1 | c.362T>A p.F121Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as COSV66438826; called by muse, mutect2, varscan2
- PTPRZ1 | c.1694T>C p.I565T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV101100865, COSV66438834; called by muse, mutect2
- RAD1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57715082; called by muse, mutect2
- RAD21 | c.762G>C p.M254I | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV52060089; called by muse, mutect2
- RASGRP4 | c.422A>T p.Q141L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV53096001; called by muse, mutect2, varscan2
- RASSF2 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65082343; called by muse, mutect2, varscan2
- RBM19 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV55693437; called by muse, mutect2, varscan2
- RBM6 | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.397); catalogued as COSV99804944; called by muse, mutect2, varscan2
- RBMXL2 | c.835C>A p.H279N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs143507713; called by muse, mutect2, varscan2
- RBP2 | c.355-2A>T p.X119_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as rs878929843, COSV99218291; called by muse, mutect2, varscan2
- RC3H1 | c.975G>T p.Q325H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51203116, COSV99280888; called by muse, mutect2, varscan2
- REG1A | c.21C>A p.Y7* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52070048; called by muse, mutect2, varscan2
- RELN | c.3044A>T p.Y1015F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.952); catalogued as COSV59009084; called by muse, mutect2, varscan2
- RET | c.1696C>A p.P566T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60698167; called by muse, mutect2, varscan2
- RFX3 | c.1755A>T p.E585D | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV56517746; called by muse, mutect2, varscan2
- RGPD2 | c.4241G>T p.G1414V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV100552907; called by mutect2, varscan2
- RGS7 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV100465945, COSV58561310; called by muse, mutect2
- RGS7 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100465954, COSV100467229; called by muse, mutect2
- RIC3 | c.521+2T>A p.X174_splice | Splice Site (SNP) | VAF 20/98 reads (20%) | catalogued as COSV58302664; called by muse, varscan2
- RIMS2 | c.2738G>A p.G913D (on ENST00000666250 / NM_001348490.2; = p.G721D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV51691034; called by mutect2, varscan2
- RIMS2 | c.4429G>T p.V1477L (on ENST00000666250 / NM_001348490.2; = p.V1048L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51691066; called by muse, mutect2, varscan2
- RIMS2 | c.4630G>T p.D1544Y (on ENST00000666250 / NM_001348490.2; = p.D1115Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51691103; called by muse, mutect2, varscan2
- RNF39 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99748218; called by muse, mutect2
- RORB | c.730G>T p.E244* (on ENST00000396204 / NM_001365023.1; = p.E233* on NM_006914.4) | Nonsense Mutation (SNP) | VAF 7/99 reads (7%) | catalogued as COSV65336711; called by muse, mutect2
- RP1 | c.6209A>G p.N2070S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs758935713, COSV55118923; called by muse, mutect2, varscan2
- RP1L1 | c.2906T>A p.I969K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV66756363; called by muse, mutect2, varscan2
- RPGRIP1 | c.2629G>T p.D877Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52852000, COSV99250688; called by muse, mutect2, varscan2
- RPN2 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.383); catalogued as COSV52906596; called by muse, mutect2, varscan2
- RSPO2 | c.51T>A p.D17E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.051); catalogued as COSV52646740; called by muse, mutect2, varscan2
- RTP2 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV64079127; called by muse, mutect2, varscan2
- RYR1 | c.10027C>G p.Q3343E | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62100329; called by muse, mutect2, varscan2
- RYR2 | c.2117A>G p.Y706C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63691176; called by muse, mutect2
- RYR2 | c.3026G>T p.R1009L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV63687404, COSV63691183; called by mutect2, varscan2
- RYR2 | c.3385G>T p.G1129C | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63696507; called by muse, mutect2, varscan2
- RYR2 | c.3386G>T p.G1129V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100767177, COSV100770288; called by muse, mutect2, varscan2
- RYR2 | c.7373C>T p.A2458V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768478443, COSV63683125; called by mutect2, varscan2
- RYR2 | c.12539del p.G4180Afs*11 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as COSV63699981; called by mutect2, pindel, varscan2
- SAMD3 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV62386686; called by muse, mutect2, varscan2
- SAXO1 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV65870512; called by muse, mutect2, varscan2
- SCP2 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65261381; called by muse, mutect2, varscan2
- SELP | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575279804, COSV55253396; called by muse, mutect2
- SELP | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV55253410, COSV99741139; called by muse, mutect2, varscan2
- SELP | c.351G>T p.W117C | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55249066, COSV55253462, COSV55259596; called by muse, mutect2
- SEMA6B | c.1232C>A p.S411* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV56704281, COSV56706459; called by muse, mutect2, varscan2
- SEMA6D | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60378906; called by muse, mutect2, varscan2
- SEMA6D | c.2513A>G p.N838S (on ENST00000316364 / NM_153618.2; = p.N776S on NM_020858.2) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs1044900350, COSV60378925; called by muse, mutect2
- SERPINA12 | c.544A>C p.S182R | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs200497328, COSV57944257; called by muse, mutect2, varscan2
- SERPINB3 | c.24C>A p.N8K | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs774496420, COSV52192137; called by muse, mutect2, varscan2
- SF3B5 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV100845559; called by muse, mutect2
- SHROOM3 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV56031590; called by mutect2, varscan2
- SI | c.5057G>T p.R1686L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52283536; called by muse, mutect2, varscan2
- SI | c.4668G>T p.R1556S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52283554, COSV52295717; called by muse, mutect2
- SIGLEC9 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV51585166; called by muse, mutect2, varscan2
- SIN3A | c.2797A>G p.I933V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV64583463; called by muse, mutect2, varscan2
- SKIL | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV52060311; called by muse, mutect2, varscan2
- SLC12A5 | c.185A>T p.E62V (on ENST00000454036 / NM_001134771.2; = p.E39V on NM_020708.5) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs376521903; called by mutect2, varscan2
- SLC17A3 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100399131; called by muse, mutect2, varscan2
- SLC22A25 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60596687; called by muse, mutect2, varscan2
- SLC32A1 | c.946A>T p.S316C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54147122; called by muse, mutect2, varscan2
- SLC5A10 | c.1405G>C p.E469Q (on ENST00000395645 / NM_001042450.4; = p.E485Q on NM_152351.5) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52413628; called by muse, mutect2, varscan2
- SLC5A11 | c.505A>T p.I169F | Missense Mutation (SNP) | VAF 21/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61742082; called by muse, mutect2
- SLC6A19 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58671150, COSV58671990; called by muse, mutect2, varscan2
- SLC8A1 | c.1579G>T p.A527S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV60484387; called by muse, mutect2, varscan2
- SLIT3 | c.3281A>T p.N1094I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV60614285; called by muse, mutect2, varscan2
- SLIT3 | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV60610565; called by muse, mutect2, varscan2
- SNUPN | c.1028A>T p.K343M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV57948662; called by muse, mutect2, varscan2
- SNX15 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV57247289; called by muse, mutect2, varscan2
- SORCS1 | c.3076C>G p.P1026A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53874675, COSV53897854; called by mutect2, varscan2
- SORL1 | c.2664-1G>T p.X888_splice | Splice Site (SNP) | VAF 13/97 reads (13%) | catalogued as COSV52756182; called by muse, mutect2, varscan2
- SPAG17 | c.3572T>C p.L1191P | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs752027681, COSV60460994; called by muse, mutect2, varscan2
- SPATA16 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV63530173; called by muse, mutect2, varscan2
- SPATA31D1 | c.3760G>A p.V1254M | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV61196992, COSV61198039; called by muse, mutect2, varscan2
- SPEG | c.7631G>T p.R2544L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV56667676, COSV56671281; called by muse, mutect2
- SPESP1 | c.741C>G p.N247K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52990318; called by muse, mutect2, varscan2
- SPOCK3 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.23); catalogued as rs138814470, COSV62728215; called by muse, mutect2, varscan2
- SPTAN1 | c.4078G>T p.G1360W | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63987827; called by muse, mutect2
- SPTLC1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV52764660; called by muse, mutect2, varscan2
- SRBD1 | c.2122G>C p.V708L | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV55400210; called by muse, mutect2
- SRCAP | c.9353G>T p.R3118L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52674760; called by muse, mutect2
- SRRM1 | c.566T>A p.V189D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV60478104; called by muse, mutect2, varscan2
- ST7 | c.1384G>T p.G462* (on ENST00000446490; = p.V539= on NM_018412.4) | Nonsense Mutation (SNP) | VAF 44/244 reads (18%) | catalogued as COSV60644817; called by mutect2, varscan2
- STRN3 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.899); catalogued as COSV62580208; called by muse, mutect2, varscan2
- STRN3 | c.543-1G>T p.X181_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100670447; called by muse, mutect2, varscan2
- SUN3 | c.13A>T p.T5S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); catalogued as COSV52051367, COSV52051710; called by muse, mutect2, varscan2
- SURF6 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV64395533; called by muse, mutect2, varscan2
- SV2B | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100370402, COSV57700353; called by muse, mutect2, varscan2
- SYNE1 | c.7174G>T p.V2392L (on ENST00000367255 / NM_182961.4; = p.V2399L on NM_033071.3) | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV55008709, COSV55053604; called by muse, mutect2, varscan2
- SYNE2 | c.669G>T p.L223F | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58361212; called by muse, mutect2
- TAF5L | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51082055; called by muse, mutect2, varscan2
- TBX3 | c.1229C>T p.P410L (on ENST00000257566 / NM_016569.4; = p.P390L on NM_005996.4) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV57472621; called by muse, mutect2
- TCEAL8 | c.210G>C p.L70F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV100749803; called by muse, mutect2, varscan2
- TECRL | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV101168665; called by muse, mutect2
- TEX15 | c.4025T>A p.V1342E (on ENST00000256246; = p.V1725E on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV56347810; called by muse, mutect2, varscan2
- TFAP2B | c.697G>T p.V233F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV53828563; called by muse, mutect2, varscan2
- TFAP2D | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV50408287; called by muse, mutect2, varscan2
- TFEC | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55402134; called by muse, mutect2, varscan2
- TG | c.4440C>A p.F1480L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV55080368; called by muse, mutect2, varscan2
- TGIF2LX | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV52213659, COSV52215155; called by mutect2, varscan2
- THSD1 | c.1660G>T p.V554L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV51629255; called by muse, mutect2, varscan2
- TLK1 | c.709G>T p.G237* | Nonsense Mutation (SNP) | VAF 43/179 reads (24%) | catalogued as COSV62630792; called by muse, mutect2, varscan2
- TLR4 | c.1213G>A p.D405N (on ENST00000355622 / NM_138554.5; = p.D365N on NM_003266.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV62923520; called by muse, mutect2, varscan2
- TMCO4 | c.1678G>T p.G560W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as COSV53873689; called by muse, mutect2, varscan2
- TMEM100 | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101448214; called by muse, mutect2, varscan2
- TMEM207 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as COSV100718945; called by muse, mutect2
- TMEM63C | c.1913A>G p.N638S | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53604506; called by muse, mutect2
- TNN | c.994C>A p.R332S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.759); catalogued as rs1046965835, COSV53428330, COSV99512723; called by muse, mutect2, varscan2
- TNS1 | c.2633-1G>C p.X878_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV50711569; called by muse, mutect2, varscan2
- TPK1 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63642211; called by muse, mutect2, varscan2
- TRAPPC9 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV101227056, COSV66896432; called by muse, mutect2, varscan2
- TREML1 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV64191314; called by muse, mutect2
- TRIML1 | c.1197C>A p.H399Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.546); catalogued as COSV60193953, COSV60194759; called by muse, mutect2, varscan2
- TRPC1 | c.2023A>G p.K675E (on ENST00000476941 / NM_001251845.2; = p.K641E on NM_003304.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV56426359; called by muse, mutect2, varscan2
- TRPC3 | c.1503G>T p.R501S (on ENST00000379645 / NM_001366479.2; = p.R428S on NM_003305.2) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV53376633; called by muse, mutect2, varscan2
- TRPM4 | c.1236A>T p.E412D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV53264201; called by muse, mutect2, varscan2
- TRPM6 | c.3054C>A p.Y1018* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV62513544; called by muse, mutect2, varscan2
- TRPS1 | c.2989C>A p.P997T (on ENST00000220888 / NM_001330599.2; = p.P1010T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as COSV55254997, COSV99629474; called by muse, mutect2
- TSC22D1 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs748065714, COSV71775803; called by muse, varscan2
- TSHZ2 | c.2420C>T p.T807I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61589395; called by muse, mutect2, varscan2
- TSHZ3 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 34/260 reads (13%) | catalogued as COSV53666129, COSV53674261; called by muse, mutect2, varscan2
- TSPAN16 | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100368271, COSV57441943; called by muse, mutect2, varscan2
- TSPOAP1 | c.4096G>T p.G1366W | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV52110630; called by muse, mutect2
- TTN | c.22183G>C p.G7395R (on ENST00000591111; = p.G6468R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | PolyPhen benign (0.226); catalogued as COSV60128051; called by muse, mutect2
- TXNL4A | c.221A>T p.E74V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99511396; called by muse, mutect2
- UBE3C | c.248G>C p.G83A | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV61953869; called by muse, mutect2, varscan2
- UGT1A7 | c.431C>G p.A144G | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV60842080; called by muse, mutect2
- UGT3A2 | c.1195G>T p.V399F | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV56931275, COSV56931336; called by muse, mutect2, varscan2
- UNC13C | c.5132C>T p.A1711V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1181771575; called by muse, mutect2
- UPP1 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV57977770, COSV57978899; called by muse, mutect2, varscan2
- USF3 | c.4520A>G p.H1507R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs750169213, COSV57074112; called by mutect2, varscan2
- USH2A | c.2228G>C p.G743A | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV56384365; called by muse, mutect2, varscan2
- USHBP1 | c.1622G>A p.G541D | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV53104150; called by muse, mutect2
- USP34 | c.5433G>C p.Q1811H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV68402394; called by muse, mutect2, varscan2
- VIT | c.656T>A p.V219E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as COSV64897119; called by muse, mutect2, varscan2
- VSIG1 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.355); catalogued as COSV54259803; called by mutect2, varscan2
- VWA8 | c.4106T>G p.I1369R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV64997360; called by muse, mutect2, varscan2
- WASHC2C | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100314284, COSV60491762; called by mutect2, varscan2
- WDR62 | c.700-2A>T p.X234_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV54335992; called by muse, mutect2, varscan2
- WNT9B | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV51518781; called by muse, mutect2, varscan2
- WSCD2 | c.591G>C p.M197I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV54584475; called by muse, mutect2, varscan2
- XIRP2 | c.3721G>A p.G1241S (on ENST00000628543; = p.G1416S on NM_152381.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54708275; called by muse, mutect2, varscan2
- XIRP2 | c.4612G>A p.V1538I (on ENST00000628543; = p.V1713I on NM_152381.6) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.51); catalogued as COSV54708290; called by muse, mutect2
- ZAN | c.3185C>A p.P1062H | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61810417; called by muse, mutect2
- ZBED1 | c.1738G>T p.V580L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.589); catalogued as COSV100585379; called by muse, mutect2
- ZBTB22 | c.1505G>C p.R502P | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV56470393, COSV99802615; called by muse, mutect2, varscan2
- ZC3H13 | c.3719G>C p.S1240T | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.078); catalogued as COSV54451143, COSV54456189; called by muse, mutect2, varscan2
- ZDBF2 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs188595104, COSV65626579; called by muse, mutect2, varscan2
- ZEB1 | c.1478A>G p.K493R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV100313961; called by muse, mutect2, varscan2
- ZFHX4 | c.5246G>C p.S1749T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV51496067, COSV99259994; called by mutect2, varscan2
- ZFHX4 | c.8033C>A p.P2678Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV50570626, COSV50623722, COSV51437950; called by muse, mutect2
- ZFP90 | c.1817A>G p.E606G | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV101238735; called by muse, mutect2, varscan2
- ZIC1 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV51551572; called by muse, mutect2, varscan2
- ZMAT1 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV100858737; called by muse, mutect2, varscan2
- ZMIZ2 | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373218484, COSV54808914; called by muse, mutect2, varscan2
- ZNF208 | c.2626C>A p.L876I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1381176752, COSV68107768; called by muse, mutect2, varscan2
- ZNF208 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as COSV68107790; called by muse, mutect2
- ZNF217 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56598243; called by muse, mutect2
- ZNF225 | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53471928; called by muse, mutect2, varscan2
- ZNF227 | c.577A>C p.K193Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV57312777; called by muse, mutect2, varscan2
- ZNF320 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.316); catalogued as rs1265160273, COSV101206846; called by muse, mutect2, varscan2
- ZNF334 | c.1870G>T p.G624* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV61618351; called by muse, mutect2, varscan2
- ZNF346 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV56156875; called by muse, mutect2
- ZNF354C | c.272C>G p.T91R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV59608631; called by muse, mutect2, varscan2
- ZNF407 | c.2935G>T p.G979* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99995226; called by muse, mutect2, varscan2
- ZNF407 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.307); catalogued as COSV99995238; called by muse, mutect2, varscan2
- ZNF440 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100407454; called by muse, mutect2, varscan2
- ZNF474 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV56946448; called by muse, mutect2, varscan2
- ZNF492 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as rs775481416, COSV71762062; called by muse, mutect2, varscan2
- ZNF493 | c.1727A>T p.K576M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV62750444; called by muse, mutect2, varscan2
- ZNF521 | c.3830C>A p.S1277Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100831701; called by muse, mutect2, varscan2
- ZNF536 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV62826148, COSV62833827; called by muse, mutect2, varscan2
- ZNF543 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100386703, COSV58627470; called by muse, mutect2
- ZNF568 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771053654, COSV61740892, COSV61741839; called by muse, mutect2, varscan2
- ZNF569 | c.572G>C p.C191S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV57596261; called by muse, mutect2, varscan2
- ZNF578 | c.1493T>C p.L498P | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1425664803, COSV69736705; called by muse, mutect2, varscan2
- ZNF611 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs1360820657, COSV60541458; called by muse, mutect2, varscan2
- ZNF616 | c.2023A>T p.N675Y | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as COSV100348320, COSV57511602; called by muse, mutect2
- ZNF622 | c.1067A>T p.H356L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV58074442; called by muse, mutect2
- ZNF8 | c.974G>T p.S325I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV52188214; called by muse, mutect2, varscan2
- ZNF804A | c.1254C>A p.C418* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV56453316; called by muse, mutect2
- ZNF804A | c.1574C>A p.P525H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV56453322; called by muse, mutect2, varscan2
- ZNF804A | c.2800C>A p.L934I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV56453334; called by muse, mutect2
- ZNF85 | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV60215312; called by muse, mutect2, varscan2
- ZNF93 | c.175G>T p.G59* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV100652217; called by muse, mutect2, varscan2
- ZP4 | c.649del p.R218Gfs*9 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs752925960; called by mutect2, pindel, varscan2
- ZZEF1 | c.5800A>C p.T1934P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as COSV67558121; called by muse, varscan2
- ABCB10 | c.1911del p.Q638Rfs*12 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- C22orf31 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD86 | c.980del p.T327Nfs*5 (on ENST00000330540 / NM_175862.5; = p.T321Nfs*5 on NM_006889.4) | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- CFAP58 | c.1849del p.V618Ffs*7 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel*
- CRTC2 | c.710_711del p.S237Ffs*9 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- DDA1 | c.197dup p.N67Efs*93 | Frame Shift Ins (INS) | VAF 24/212 reads (11%) | called by mutect2, pindel, varscan2
- FAT2 | c.5451del p.S1818Afs*5 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- FBXW10 | c.2637_2638del p.K880Tfs*7 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, varscan2
- FER1L6 | c.1715dup p.L572Ffs*4 | Frame Shift Ins (INS) | VAF 29/125 reads (23%) | called by mutect2, pindel, varscan2
- GRB10 | c.940_941dup p.L314Ffs*35 (on ENST00000398812; = p.L256Ffs*35 on NM_001001550.3) | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- IGHM | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- IGHV2-26 | c.45C>A p.S15= | Splice Region (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2
- IGKV1-6 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); called by muse, mutect2
- IGKV3D-11 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- KRTAP13-4 | c.15C>A p.C5* | Nonsense Mutation (SNP) | VAF 6/111 reads (5%) | called by muse, mutect2
- LCTL | c.80del p.P27Qfs*59 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- MAGEB6B | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAMLD1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2
- OR2F2 | c.318_319delinsG p.L107Wfs*11 | Frame Shift Del (DEL) | VAF 15/119 reads (13%) | called by pindel, varscan2*
- ORAI3 | c.473del p.G158Afs*125 | Frame Shift Del (DEL) | VAF 15/158 reads (9%) | called by mutect2, pindel, varscan2
- PCLO | c.12522del p.A4175Qfs*21 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | called by mutect2, pindel, varscan2
- PLPBP | c.667_668insAT p.M223Nfs*14 | Frame Shift Ins (INS) | VAF 12/95 reads (13%) | called by muse*, mutect2
- PLPBP | c.670_671del p.G224Hfs*10 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | called by muse*, mutect2
- PRAMEF18 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TINAG | c.1294del p.W432Gfs*23 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- TPTE | c.960G>T p.K320N (on ENST00000618007 / NM_199261.4; = p.K302N on NM_199259.4) | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.27); called by muse, mutect2
- TRAV8-7 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.019); called by muse, mutect2
- USH2A | c.9312del p.T3105Lfs*55 | Frame Shift Del (DEL) | VAF 14/141 reads (10%) | called by mutect2, varscan2
- VGLL3 | c.202_203insT p.E68Vfs*18 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel*, varscan2*
- VN1R5 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WASHC2A | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- XPO4 | c.2568A>G p.I856M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); called by muse, mutect2
- ZNF184 | c.1923dup p.Y642Lfs*4 | Frame Shift Ins (INS) | VAF 8/81 reads (10%) | called by mutect2, pindel, varscan2
- ZNF605 | c.14A>T p.Q5L | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.901); called by muse, varscan2
- ZNF831 | c.2598del p.G868Afs*27 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by pindel, varscan2
- ABCA7 | c.4452G>T p.V1484= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV54031520; called by muse, mutect2, varscan2
- ABCG1 | c.153A>T p.G51= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV59205722; called by muse, mutect2, varscan2
- ACAN | c.5016C>A p.A1672= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV61362297; called by muse, mutect2
- ADAM19 | c.2379C>A p.P793= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV57431841; called by muse, mutect2, varscan2
- ADAMTS12 | c.4716C>G p.P1572= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV100710440, COSV61265682; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2331G>C p.G777= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV54452747, COSV99718789; called by muse, mutect2, varscan2
- AHCY | c.1041G>A p.L347= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV54153515; called by muse, mutect2, varscan2
- AHNAK2 | c.2796G>A p.K932= | Silent (SNP) | VAF 24/320 reads (8%) | catalogued as COSV60918368; called by muse, mutect2
- AKR1E2 | c.66A>G p.A22= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV53630734; called by muse, mutect2
- ALPK1 | c.1161G>T p.G387= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99453502; called by muse, mutect2, varscan2
- ANKRD30A | c.1968C>G p.A656= (on ENST00000611781; = p.A600= on NM_052997.2) | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100653152, COSV64612690; called by muse, mutect2, varscan2
- AP2A1 | c.1002G>T p.L334= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100756198; called by muse, mutect2, varscan2
- ARL6IP1 | c.159T>C p.S53= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV58614518; called by muse, mutect2
- ASTN1 | c.438A>G p.E146= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV56072315; called by muse, mutect2, varscan2
- AURKC | c.318G>T p.L106= (on ENST00000302804 / NM_001015878.2; = p.L72= on NM_003160.3) | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV57139908; called by muse, mutect2, varscan2
- B3GALNT1 | c.69G>T p.L23= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100251960; called by muse, mutect2, varscan2
- C5AR1 | c.381G>T p.L127= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV61892742; called by muse, mutect2, varscan2
- CASZ1 | c.4119G>T p.R1373= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- CCDC27 | c.87C>A p.S29= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV53900983; called by muse, mutect2, varscan2
- CCDC54 | c.141T>A p.T47= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV53758884; called by muse, mutect2, varscan2
- CCT8L2 | c.528C>A p.P176= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100742624; called by muse, mutect2, varscan2
- CD109 | c.2481G>T p.L827= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV54651268; called by muse, mutect2, varscan2
- CEACAM20 | c.1599G>A p.E533= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1170823184, COSV57602012; called by muse, mutect2
- CERS4 | c.687G>A p.L229= | Silent (SNP) | VAF 47/249 reads (19%) | catalogued as rs1435527427, COSV52167749; called by muse, mutect2, varscan2
- CHRNA6 | c.1008A>T p.T336= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs373535041; called by mutect2, varscan2
- CNGB3 | c.2301C>A p.P767= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- DDR2 | c.1896C>A p.L632= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV63371778; called by muse, mutect2, varscan2
- DGKA | c.51A>G p.Q17= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1189800584, COSV59386536; called by muse, mutect2, varscan2
- DLGAP1 | c.2097A>T p.A699= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV59811665; called by muse, mutect2, varscan2
- DLK1 | c.186C>A p.G62= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV57991998; called by muse, mutect2
- DMD | c.246G>T p.R82= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55878590; called by muse, mutect2, varscan2
- DNAH9 | c.4368G>A p.R1456= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV52355115; called by muse, mutect2, varscan2
- DTX3L | c.1050T>A p.I350= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV56144517; called by muse, mutect2, varscan2
- ENTPD5 | c.978C>T p.F326= | Silent (SNP) | VAF 16/210 reads (8%) | catalogued as COSV58222591; called by muse, mutect2
- ETS1 | c.444C>G p.A148= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV60094204; called by muse, mutect2
- FAM126A | c.1485A>T p.S495= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV69471905; called by muse, mutect2, varscan2
- FAT4 | c.7062A>T p.V2354= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV100627888, COSV58696269; called by muse, mutect2
- FBXO40 | c.1200C>A p.L400= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV57524778; called by muse, mutect2, varscan2
- FCER1G | c.219G>A p.Q73= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV57155130; called by muse, mutect2
- FCRL5 | c.2427G>T p.L809= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100708992, COSV62515639, COSV62516235; called by muse, mutect2, varscan2
- FNDC5 | c.399C>A p.S133= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as COSV100992467; called by muse, mutect2, varscan2
- FZD7 | c.78G>C p.L26= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs35732430, COSV53811586; called by muse, mutect2, varscan2
- GAST | c.111G>T p.G37= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV61475631; called by muse, mutect2, varscan2
- GPR158 | c.2730G>A p.K910= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as rs201167926, COSV66272833; called by muse, mutect2, varscan2
- GRIA2 | c.363A>T p.T121= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV52394081; called by muse, mutect2
- GUCY2F | c.2931C>A p.V977= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV54303917; called by muse, mutect2, varscan2
- HAUS3 | c.1470A>T p.A490= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV54723004; called by muse, mutect2, varscan2
- HIVEP1 | c.3555C>T p.H1185= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1302163134, COSV65099189; called by muse, mutect2, varscan2
- HS3ST2 | c.384G>C p.R128= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV54463521; called by muse, mutect2
- ILVBL | c.555T>A p.I185= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV99654699; called by muse, mutect2
- ITGAD | c.381G>T p.L127= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101210362; called by muse, mutect2
- JCAD | c.183G>C p.A61= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV64760159; called by muse, mutect2, varscan2
- KCNA2 | c.1479C>G p.T493= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV60370623; called by muse, mutect2, varscan2
- KCNJ16 | c.567T>G p.L189= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99388082; called by muse, mutect2, varscan2
- KIR3DL1 | c.327C>A p.P109= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV58492218, COSV58494984; called by muse, mutect2, varscan2
- KIRREL2 | c.423T>A p.P141= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV52877241; called by muse, mutect2, varscan2
- KMT2B | c.2250C>T p.P750= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1215532575, COSV52890957; called by muse, mutect2, varscan2
- KRTAP13-3 | c.237C>A p.S79= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100481724; called by muse, mutect2, varscan2
- L3MBTL3 | c.348G>T p.G116= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100695861, COSV62386729; called by mutect2, varscan2
- LAMB1 | c.3639C>A p.I1213= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV55966155; called by muse, mutect2, varscan2
- LCE2C | c.210C>A p.G70= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV100909407; called by muse, mutect2, varscan2
- LILRB3 | c.1803C>G p.A601= (on ENST00000346401; = p.A589= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV54437969; called by muse, mutect2, varscan2
- LRP12 | c.2274A>G p.R758= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV52630019; called by muse, mutect2
- LRRTM1 | c.1482G>T p.P494= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1156419034, COSV54443255, COSV54443591; called by muse, mutect2, varscan2
- MBL2 | c.721C>T p.L241= | Silent (SNP) | VAF 26/234 reads (11%) | catalogued as rs1258901308, COSV64758725, COSV64759227; called by muse, mutect2, varscan2
- MROH7 | c.1342C>T p.L448= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs868817022, COSV59873313; called by muse, mutect2, varscan2
- MSC | c.564G>T p.P188= | Silent (SNP) | VAF 30/350 reads (9%) | catalogued as COSV57696915; called by muse, mutect2
- MUC3A | c.7965A>T p.T2655= | Silent (SNP) | VAF 26/454 reads (6%) | catalogued as COSV60217649; called by muse, mutect2
- MXRA5 | c.3942A>T p.P1314= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs747807135, COSV54238695; called by muse, mutect2, varscan2
- MYBPC2 | c.2121C>A p.I707= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV63096500; called by muse, mutect2
- MYL4 | c.447G>T p.T149= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100733094; called by muse, mutect2, varscan2
- NCAM1 | c.1260C>A p.G420= (on ENST00000316851 / NM_181351.5; = p.G410= on NM_000615.7) | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV57518353; called by muse, mutect2
- NOTCH3 | c.5841G>T p.A1947= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV104373768, COSV54637667; called by muse, mutect2
- NRG2 | c.1702C>A p.R568= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV56834394; called by muse, mutect2, varscan2
- NT5C3B | c.438C>T p.Y146= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV54056372; called by muse, mutect2, varscan2
- NYAP1 | c.705T>C p.A235= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100278400; called by muse, mutect2, varscan2
- OLA1 | c.486C>T p.P162= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs570495275, COSV52971234; called by mutect2, varscan2
- OR11A1 | c.171C>A p.L57= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV65821110; called by muse, mutect2, varscan2
- OR2M2 | c.717G>T p.T239= | Silent (SNP) | VAF 44/238 reads (18%) | catalogued as COSV100677199, COSV62898574; called by muse, mutect2, varscan2
- OR2M5 | c.6A>G p.A2= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV63546125; called by muse, mutect2, varscan2
- OR4K5 | c.597T>C p.I199= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as COSV60003892; called by muse, mutect2, varscan2
- OR51V1 | c.255G>T p.L85= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100343304, COSV100343511; called by muse, mutect2, varscan2
- OR52K2 | c.81C>A p.I27= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV57835278; called by muse, mutect2, varscan2
- OR52N5 | c.609C>A p.V203= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV57699016; called by muse, mutect2, varscan2
- OR52R1 | c.666G>T p.V222= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100617665; called by muse, mutect2
- OR56B1 | c.930C>A p.A310= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as COSV100402760, COSV57723293; called by muse, mutect2, varscan2
- OR5V1 | c.87C>A p.T29= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs1442658152, COSV65828432; called by muse, mutect2, varscan2
- OR8K5 | c.265C>A p.R89= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs147577134, COSV57889485; called by mutect2, varscan2
- PALLD | c.1408C>T p.L470= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV54983279; called by muse, mutect2, varscan2
- PCDH11X | c.2772A>T p.T924= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV53474852; called by muse, mutect2, varscan2
- PCDHB8 | c.1890G>A p.L630= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1308865451, COSV50777692; called by muse, mutect2, varscan2
- PCDHGA1 | c.1398C>T p.P466= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV65297122; called by muse, mutect2
- PCDHGA8 | c.1734G>T p.A578= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs771070854, COSV53966619, COSV54057843; called by muse, mutect2, varscan2
- PDE3A | c.1110G>T p.V370= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV62975148; called by muse, mutect2, varscan2
- PDGFRA | c.2517G>T p.L839= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as rs1213039385, COSV57269465; ClinVar: likely benign; called by muse, mutect2
- PDZD4 | c.939C>A p.R313= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV51247541; called by muse, mutect2, varscan2
- PER1 | c.1098C>A p.P366= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV57920146; called by mutect2, varscan2
- PHF20L1 | c.282G>C p.L94= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55193992, COSV99621212; called by muse, mutect2
- PIGT | c.591C>T p.S197= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV54126835; called by muse, mutect2
- PIK3AP1 | c.1125C>T p.P375= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV59533690; called by muse, mutect2
- PIK3R2 | c.1260G>C p.R420= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV55848504; called by muse, mutect2, varscan2
- PLB1 | c.535C>T p.L179= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as rs1377060414, COSV59827925; called by muse, mutect2, varscan2
- PLD4 | c.1155C>A p.P385= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101190475; called by muse, mutect2
- PLOD3 | c.1821G>T p.V607= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV56183603; called by muse, mutect2
- PLPP7 | c.243C>A p.A81= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV64836039; called by muse, mutect2, varscan2
- PLPPR4 | c.2275C>A p.R759= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs998231690, COSV64564142, COSV64565285; called by muse, mutect2, varscan2
- POGZ | c.3816C>G p.V1272= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as COSV51851881; called by muse, mutect2
- PROS1 | c.531T>C p.N177= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV62398754; called by muse, mutect2
- PSG2 | c.675C>T p.A225= | Silent (SNP) | VAF 33/325 reads (10%) | catalogued as COSV61545556; called by muse, mutect2, varscan2
- PSMB9 | c.570G>C p.G190= | Silent (SNP) | VAF 42/225 reads (19%) | catalogued as COSV66399651; called by muse, mutect2, varscan2
- PTPRH | c.1515C>A p.S505= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99670860; called by mutect2, varscan2
- QRICH2 | c.1818C>A p.V606= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs767200620, COSV53154272, COSV53157212; called by muse, mutect2, varscan2
- RASAL1 | c.954G>A p.L318= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs137930457, COSV55656940; called by muse, mutect2, varscan2
- RBM6 | c.2775C>T p.P925= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99804947; called by muse, mutect2, varscan2
- RBP4 | c.279C>G p.G93= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV65160356, COSV65160672; called by muse, mutect2, varscan2
- REG3G | c.18C>A p.A6= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99709323; called by muse, mutect2
- RNF215 | c.318A>T p.P106= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV53176299; called by muse, mutect2, varscan2
- RYR1 | c.8655G>T p.T2885= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100615186, COSV62115774; called by muse, mutect2, varscan2
- RYR3 | c.6189G>T p.L2063= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV66794606; called by muse, mutect2, varscan2
- RYR3 | c.6750C>A p.I2250= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV63109694; called by muse, mutect2
69 further variants in this file (0 protein-altering or splice-affecting, 46 silent, 23 other) are not listed here.
